TCGA case TCGA-YU-A90Z — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a86c193c-ba02-408b-a253-7051f9401793

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 28 years; Year of birth: 1983; Vital status: Dead; Days to death: 1,209 days (3.3 years); Year of death: 2014; Cause of death: Not Cancer Related; Cause of death source: Death Certificate.

Diagnoses (2)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 28.0 years (10,231 days); Year of diagnosis: 2011; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical N: N3; AJCC clinical M: M0; AJCC clinical stage: Stage IIIC; AJCC pathologic T: T2; AJCC pathologic stage: Stage IIIC; IGCCCG stage: Good Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,209 days (3.3 years); Ajcc serum tumor markers: S3; Sites of involvement: Epididymis.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Post Adjuvant Therapy.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin; Treatment intent type: Adjuvant; Days to treatment start: 12 days; Days to treatment end: 69 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Seminoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 30.9 years (11,300 days); Days to diagnosis: 1,069 days (2.9 years); Prior treatment: Yes.

Follow-up (5 entries)
- Days to follow up: 961 days (2.6 years); Disease response: Tumor Free.
- Day 1,069 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 1,069 days (2.9 years).
- Days to follow up: 1,118 days (3.1 years); Disease response: With Tumor.
- Days to follow up: 1,209 days (3.3 years); Disease response: With Tumor.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -8: Lactate Dehydrogenase 6939; Alpha Fetoprotein 176; Human Chorionic Gonadotropin 399.
- Day 19: Lactate Dehydrogenase 864; Alpha Fetoprotein 88.2; Human Chorionic Gonadotropin 3.54.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YU-A90Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 280 mg.
  Slide TCGA-YU-A90Z-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YU-A90Z-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YU-A90Z-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
